Gene-level copy-number profile of tumor specimen ALCH-AD6V-TTP1-A from ALCHEMIST case ALCH-AD6V, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.4 years (26,094 days).
Specimen ALCH-AD6V-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 153355a7-53d8-416c-8911-637694767544.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AD6V-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/10e8ae02-6c0e-4e9e-8d20-389819e8b2b5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 937; copy number 2: 24,221; copy number 3: 16,448; copy number 4: 11,178; copy number 5: 5,168; copy number 6: 260; copy number 7: 122; copy number 8: 1; copy number 9: 2; copy number 10: 9; copy number 11: 1; copy number 26: 2; copy number 35: 3; copy number 72: 14; copy number 87: 2; copy number 111: 1; copy number 123: 10; copy number 148: 6.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:33,207,129–33,225,850, 3 genes (within-gene range 0–2): AC008738.7, SLC7A10, AC008738.4.
- chr21:45,478,266–45,478,326, 1 gene (within-gene range 0–2): MIR6815.
- chr22:21,354,563–21,358,067, 1 gene: LINC01651.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,601 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,512,653–8,513,021, 1 gene, copy number 5 (within-gene range 4–5): AL096855.2.
- chr1:143,419,625–168,075,843, 951 genes, copy number 5 (broad region; genes not listed).
- chr1:194,188,967–205,896,082, 241 genes, copy number 5–9 (broad region; genes not listed).
- chr1:246,509,038–248,937,043, 127 genes, copy number 5 (broad region; genes not listed).
- chr4:48,497,357–48,780,322, 1 gene, copy number 6 (within-gene range 4–6): FRYL.
- chr4:48,805,212–49,562,149, 24 genes, copy number 5–6: OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4, AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24.
- chr7:37,032–5,513,809, 116 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:5,620,047–27,844,564, 353 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:29,122,340–29,514,667, 2 genes, copy number 5 (within-gene range 4–5): AC004593.2, CHN2.
- chr7:29,514,224–45,186,302, 300 genes, copy number 5 (broad region; genes not listed).
- chr7:45,912,245–48,647,497, 30 genes, copy number 5: IGFBP3, AC073115.2, AC073115.1, FTLP15, TTC4P1, ZNF619P1, AC023669.1, AC023669.2, AC004869.2, AC004869.1, HMGN1P19, AC011294.1, EPS15P1, AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1, TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57, UPP1, ABCA13.
- chr7:49,773,638–53,188,938, 35 genes, copy number 5: VWC2, ZPBP, GNL2P1, AC034148.1, SPATA48, AC020743.1, AC020743.2, AC020743.3, IKZF1, AC124014.1, RNU6-1091P, FIGNL1, DDC, DDC-AS1, GRB10, AC005153.1, AC004920.1, AC009296.1, AC004830.2, AC004830.1, COBL, RPL7L1P2, CICP17, AC012441.2, AC012441.1, AC005999.2, ROBO2P1, AC005999.1, RN7SL292P, AC079763.1, AC006320.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1.
- chr7:89,443,946–89,754,726, 2 genes, copy number 5: AC002383.1, RNU6-274P.
- chr7:90,383,721–98,215,457, 131 genes, copy number 5–148 (within-gene range 1–148) (broad region; genes not listed).
- chr7:98,252,379–102,283,958, 161 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr8:68,880,139–75,377,014, 114 genes, copy number 5 (broad region; genes not listed).
- chr8:86,333,274–94,262,350, 102 genes, copy number 5 (broad region; genes not listed).
- chr8:94,371,960–145,066,685, 796 genes, copy number 5–7 (broad region; genes not listed).
- chr14:18,333,726–25,267,336, 472 genes, copy number 5–10 (broad region; genes not listed).
- chr14:28,673,241–28,830,204, 7 genes, copy number 7: BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281.
- chr14:30,559,158–42,268,586, 181 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr15:43,746,410–43,773,278, 1 gene, copy number 6 (within-gene range 2–6): PDIA3.
- chr16:11,555–32,460,362, 1,239 genes, copy number 5 (broad region; genes not listed).
- chr16:32,600,299–35,104,834, 96 genes, copy number 5 (broad region; genes not listed).
- chr18:316,737–4,455,307, 87 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr21:9,053,122–9,129,752, 4 genes, copy number 10: CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.
- chr21:44,107,373–44,210,114, 2 genes, copy number 5 (within-gene range 3–26): PWP2, GATD3A.
- chr21:44,172,169–44,194,338, 2 genes, copy number 26: AP001056.2, AP001056.1.
- chr22:21,341,595–21,345,258, 1 gene, copy number 7: PPP1R26P5.
- chr22:21,370,064–21,471,269, 5 genes, copy number 5–11: AP000552.1, Metazoa_SRP, Metazoa_SRP, HIC2, TMEM191C.
- chr22:38,861,422–39,155,945, 17 genes, copy number 6–7: CBX6, AL022318.1, APOBEC3A, APOBEC3B, APOBEC3B-AS1, APOBEC3C, AL022318.4, APOBEC3D, APOBEC3F, AL022318.2, APOBEC3G, AL031846.1, APOBEC3H, CBX7, COX5BP7, AL031846.2, FUNDC2P4.

Autosomal genes at a single copy (total copy number 1): 937. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
